Gene-level copy-number profile of tumor specimen C3N-04293-02 from CPTAC case C3N-04293, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.7 years (27,654 days).
Specimen C3N-04293-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6596739b-b382-4fc0-9a0c-8b2dd4d81bce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04293-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/0f2f94c4-fa41-404e-be67-677ae9d9eeb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 8,333; copy number 2: 41,514; copy number 3: 5,288; copy number 4: 1,747; copy number 5: 62; copy number 6: 546; copy number 7: 1,342.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:131,025–157,887, 5 genes (within-gene range 0–6): CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr8:7,715,443–8,049,267, 30 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,089,089, 2 genes: AC105233.2, MIR548I3.
- chr8:12,333,644–12,665,588, 14 genes (within-gene range 0–1): RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr9:16,625,676–16,626,390, 1 gene (within-gene range 0–1): AL450003.1.
- chr11:89,960,422–90,087,131, 13 genes: AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:9,975,017–10,137,004, 4 genes: CR382285.1, CR382285.2, CR382287.1, CDRT15P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,950 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–133,723, 4 genes, copy number 5–6 (within-gene range 0–6): OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr7:63,011,463–143,523,449, 1,596 genes, copy number 5–7 (broad region; genes not listed).
- chr7:143,754,628–159,233,377, 293 genes, copy number 6 (broad region; genes not listed).
- chr12:459,939–1,788,674, 24 genes, copy number 5: B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr22:44,172,956–45,448,743, 33 genes, copy number 5: PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1.

Autosomal genes at a single copy (total copy number 1): 5,990. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
